Somatic mutation profile of tumor specimen HCM-BROD-0055-C64-01A (aliquot HCM-BROD-0055-C64-01A-11D-A79L-36) from HCMI case HCM-BROD-0055-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.4 years (162 days).
Specimen HCM-BROD-0055-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbb61bdd-d73f-487b-9c49-d5ccef14f4ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0055-C64-11A (Solid Tissue Normal), aliquot HCM-BROD-0055-C64-11A-11D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81ea63a5-1935-457a-a1d7-6bdb7108482f

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RTL3 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
